FM case AD15181 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/fd7cfd1a-08cd-4a3d-9e40-1de422b34d77

Female, 54.2 years: diagnosis not reported by GDC of the breast; metastasis biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
